Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABKD, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABKD-TTP1-A (Primary Tumor).

Material description

- A) Lower pulmonary lobe, right lung
- B) Lobar hilum lymph nodes
- C) Paraesophageal lymph nodes

CDDP-YP-ABKD-01-PR

Macro description

A) 14 x 10 x 4 cm lower pulmonary right lobe. On the costal side, to 3 cm from the bronchial tree, the pleura is focally dusty and retracted. In this place there is, when you cut, a greyish neoformation, with irregular margins, of 3,2 x 2.5 x 2 cm. The remaining parenchyma is free of important alterations. We close off 10 peribronchial lymph nodes (A1 bronchial and vascular margins; A2 peribronchial lymph nodes, A3 neoformation of the pleura; A4 neoformation; A5 parenchyma at distance; A6 peribronchial intraparenchymal lymph nodes).

B) 3 lymph nodes with bigger axis between 0.4 cm and 0.7 cm

C) 2 lymph nodes with bigger axis of 1.5 cm and 0.4 cm.

Micro description

A) Pulmonary acinar adenocarcinoma (WHO 1999), poorly differentiated (G3), infiltrating the parenchyma.

Pleura and remaining parenchyma free of neoplasm. Margin of bronchial and vascular resection free of neoplasm with focal epithelial squamous metaplasia of the bronchial margin.

The 10 found peribronchial lymph nodes free of metastases

Colorazioni speciali eseguite: Alcian — PAS

B) 2 lymph nodes free of metastases

C) 3 lymph nodes free of metastases

Staging pTNM: pT2,N0

ICD-0-3

adenocarcinoma, acinar 8550/3
Site: (R) lung, lower lobe C34.3

ICD-10

C34.31

hw
2/12/16

Source: NCI Genomic Data Commons file f6682c9f-ec42-4506-a39e-87c1f0eec3a6 (CDDP-ABKD-TTP1.68B9C93A-D0F1-42E6-A9D2-9621163DC18C.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).